Somatic mutation profile of tumor specimen TCGA-CI-6622-01A (aliquot TCGA-CI-6622-01A-11D-1826-10) from TCGA case TCGA-CI-6622, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.8 years (27,336 days).
Specimen TCGA-CI-6622-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9c9db67-0ac6-43e8-a788-13e100ab008d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CI-6622-10A (Blood Derived Normal), aliquot TCGA-CI-6622-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cc73c95-75a2-414f-842f-018ca6d0e085

The open-access MAF lists 116 somatic variants for this specimen: 76 protein-altering or splice-affecting, 38 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 38, Nonsense Mutation 6, Intron 2, Frame Shift Ins 1, Splice Site 1, In Frame Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 31/97 reads (32%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSBG2 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.449); catalogued as rs749827875, COSV53127528; called by muse, mutect2, varscan2
- ACTR5 | c.333G>C p.L111F | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV54762099; called by muse, mutect2, varscan2
- ADGRA2 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.471); catalogued as rs762378669, COSV59446937; called by muse, mutect2, varscan2
- ADGRV1 | c.12464C>T p.P4155L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as rs765063091, COSV101316224; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGO2 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV55052318; called by muse, mutect2, varscan2
- ANO2 | c.2848G>T p.E950* (on ENST00000356134 / NM_001278597.3; = p.E954* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV59041192; called by muse, mutect2, varscan2
- ARFGEF3 | c.2251G>A p.G751S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs765088385, COSV52449428; called by muse, mutect2, varscan2
- ATP8B4 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs370938976, COSV52711717; called by muse, mutect2, varscan2
- BRSK1 | c.1104C>A p.D368E | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.145); catalogued as COSV58669633; called by muse, mutect2, varscan2
- C19orf18 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 42/144 reads (29%) | catalogued as COSV58707895; called by muse, mutect2, varscan2
- CADPS2 | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs915554264, COSV57383273; called by muse, mutect2, varscan2
- CCDC105 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV52965537; called by muse, mutect2, varscan2
- CDHR2 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs762273064, COSV56144504; called by muse, mutect2, varscan2
- CKAP2 | c.1296C>A p.N432K (on ENST00000378037 / NM_001098525.2; = p.N431K on NM_018204.5) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV51624380; called by muse, mutect2, varscan2
- CSMD1 | c.9262C>T p.P3088S (on ENST00000520002; = p.P3087S on NM_033225.6) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100151089; called by muse, mutect2, varscan2
- DCAF4L2 | c.892G>T p.D298Y | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60481985; called by muse, mutect2, varscan2
- DDX58 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV65884689; called by muse, mutect2, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DHX8 | c.3323G>A p.C1108Y | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99292447; called by muse, mutect2, varscan2
- DYRK1A | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766592662, COSV58296899; called by muse, mutect2, varscan2
- EPB41L3 | c.2121G>A p.E707= | Splice Region (SNP) | VAF 9/16 reads (56%) | catalogued as rs983672528, COSV59466266; called by muse, mutect2, varscan2
- FRYL | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV99977534; called by muse, mutect2, varscan2
- GABRB3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs144496462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBP7 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs772256061, COSV54011680; called by muse, mutect2, varscan2
- GCK | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs757888672, CM051930, COSV56268912; called by muse, mutect2, varscan2
- GPR157 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs1261938423, COSV66234320; called by muse, mutect2, varscan2
- GPR22 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs377315363; called by muse, mutect2, varscan2
- HYDIN | c.11426A>G p.D3809G | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as COSV101125147; called by muse, varscan2
- INO80C | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1260281669, COSV58048693; called by muse, mutect2, varscan2
- JHY | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs139995595, COSV57078751; called by muse, mutect2, varscan2
- KRTAP6-2 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 63/192 reads (33%) | PolyPhen probably damaging (0.987); catalogued as rs533416500, COSV58182373; called by muse, mutect2, varscan2
- LARP1B | c.668+1G>A p.X223_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV52802458; called by muse, mutect2, varscan2
- LTBP3 | c.1544A>G p.D515G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as COSV57243755; called by muse, mutect2, varscan2
- MMP16 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs138174209, COSV54164626; called by muse, mutect2, varscan2
- MROH8 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs556574052, COSV54124241; called by muse, mutect2, varscan2
- MTMR8 | c.1524G>T p.Q508H | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66392242; called by muse, mutect2, varscan2
- MYO5A | c.1660G>T p.A554S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV62564274; called by muse, mutect2, varscan2
- NAP1L1 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV53873658; called by muse, mutect2, varscan2
- NETO1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919067181, COSV55014649; called by muse, mutect2, varscan2
- NFE2 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV100380807; called by muse, mutect2, varscan2
- NUMA1 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as rs779257804, COSV61190613; called by muse, mutect2, varscan2
- OCIAD2 | c.115A>T p.I39F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.564); catalogued as COSV56717478; called by muse, mutect2, varscan2
- ODF3L2 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.345); catalogued as rs1033827967, COSV52749121; called by muse, mutect2, varscan2
- OR2A5 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV68739088; called by muse, mutect2, varscan2
- OR52E2 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs267602936, COSV58611784; called by muse, mutect2, varscan2
- OR5D14 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV59458306; called by muse, mutect2, varscan2
- PARP6 | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53004950; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCBP2 | c.1076C>T p.T359M (on ENST00000439930 / NM_001128911.2; = p.T360M on NM_005016.6) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV57235796; called by muse, mutect2, varscan2
- PCDHA9 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.329); catalogued as COSV65331504; called by muse, mutect2, varscan2
- PIM1 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV65166455; called by muse, mutect2, varscan2
- PSG4 | c.575G>T p.R192M | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54934074, COSV54940253; called by muse, mutect2, varscan2
- RAPGEF6 | c.3830G>A p.S1277N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57240468; called by muse, mutect2, varscan2
- RBM7 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs752632231, COSV64955935; called by muse, mutect2, varscan2
- RPS6KA2 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV55829377; called by muse, mutect2, varscan2
- RYR2 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100771991; called by muse, mutect2, varscan2
- SLC28A1 | c.1394C>T p.S465F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs765719750, COSV99723251; called by muse, mutect2, varscan2
- SLC6A19 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs750499474, COSV58674261; called by muse, mutect2, varscan2
- SOS1 | c.3610A>G p.I1204V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs374497013; called by muse, mutect2, varscan2
- SOX9 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV55428175; called by muse, mutect2, varscan2
- TMEM182 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 94/292 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs767689957, COSV68425032; called by muse, varscan2
- TMOD3 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs757302528, COSV57946030; called by muse, mutect2, varscan2
- TTN | c.48967A>T p.T16323S (on ENST00000591111; = p.T8899S on NM_003319.4) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | PolyPhen benign (0.013); catalogued as COSV60035764, COSV60309771; called by muse, mutect2, varscan2
- UGGT2 | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV65078900; called by muse, mutect2, varscan2
- UNC5A | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56165312; called by muse, mutect2, varscan2
- USH2A | c.7198G>A p.D2400N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs370204550; called by muse, mutect2, varscan2
- ZAN | c.3145C>T p.R1049C | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs759611480, COSV100769961, COSV61811172; called by muse, mutect2, varscan2
- ZBTB21 | c.2859G>T p.W953C | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60405577; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2515G>A p.V839I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs371159477; called by muse, mutect2, varscan2
- ZDHHC4 | c.24G>C p.L8F | Missense Mutation (SNP) | VAF 14/375 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1329573318, COSV100254008; called by muse, mutect2
- FGF5 | c.692_693dup p.T232Lfs*29 | Frame Shift Ins (INS) | VAF 24/76 reads (32%) | called by mutect2, pindel, varscan2
- KRAS | c.30_35dup p.A11_G12dup | In Frame Ins (INS) | VAF 28/91 reads (31%) | called by mutect2, varscan2
- ADAMTS5 | c.573C>T p.H191= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs1215533823, COSV53180584, COSV53184616; called by muse, mutect2, varscan2
- AFAP1L1 | c.204C>T p.F68= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1167132674, COSV57044505; called by muse, mutect2, varscan2
- AGAP2 | c.3027C>T p.R1009= (on ENST00000547588 / NM_001122772.2; = p.R653= on NM_014770.4) | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV57730418; called by muse, mutect2, varscan2
- AHNAK | c.2166G>A p.L722= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as rs1565245029, COSV57228647; called by muse, mutect2, varscan2
- AP2A1 | c.1077C>T p.S359= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs764972118, COSV100756399; called by muse, mutect2, varscan2
- ARFGEF3 | c.4617G>A p.L1539= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV52469586; called by muse, mutect2, varscan2
- CACNA1H | c.4890C>T p.N1630= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs758400171, COSV100673209; called by muse, mutect2, varscan2
- CFAP74 | c.246C>T p.S82= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs770664201, COSV54573302; called by muse, mutect2, varscan2
- CPNE2 | c.45C>T p.A15= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1329271940, COSV51964729; called by muse, mutect2, varscan2
- CYP2C8 | c.1398C>T p.N466= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV64878795; called by muse, mutect2, varscan2
- DCLK3 | c.354C>T p.H118= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as rs552055548, COSV69364600; called by muse, mutect2, varscan2
- FBN2 | c.4872C>A p.V1624= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV52542811; called by muse, mutect2, varscan2
- FOXK1 | c.1974G>A p.P658= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs570756478, COSV61065034, COSV61068435; called by muse, mutect2, varscan2
- GIN1 | c.1209C>A p.V403= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV67537705; called by muse, mutect2, varscan2
- GPR149 | c.807G>A p.P269= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV67666634; called by muse, mutect2, varscan2
- GRK5 | c.1626T>C p.P542= | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- HIVEP3 | c.3654G>A p.R1218= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV56022682; called by muse, mutect2, varscan2
- KLHL40 | c.1110C>T p.N370= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs201966674, COSV55137092; called by muse, mutect2, varscan2
- L3MBTL1 | c.1026G>A p.P342= (on ENST00000418998 / NM_001377303.1; = p.P252= on NM_015478.7) | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs371655802; called by muse, mutect2, varscan2
- LILRB1 | c.1188G>A p.E396= (on ENST00000427581; = p.E360= on NM_006669.6) | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as rs1248700830, COSV61116320, COSV61121382; called by muse, mutect2
- LRBA | c.7176A>G p.E2392= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV63963684; called by muse, mutect2, varscan2
- MFN2 | c.1626G>A p.E542= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV52425343; called by muse, mutect2, varscan2
- MORC1 | c.2421G>A p.A807= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs543158461, COSV99226965; called by muse, mutect2, varscan2
- MTMR6 | c.1083C>A p.I361= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV67809687; called by muse, mutect2, varscan2
- NLGN4X | c.2178C>T p.N726= | Silent (SNP) | VAF 47/68 reads (69%) | catalogued as rs187221748, COSV52020249; called by muse, mutect2, varscan2
- NNT | c.3240T>A p.V1080= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV52929113; called by muse, mutect2, varscan2
- PCDHA10 | c.1458C>T p.N486= | Silent (SNP) | VAF 53/171 reads (31%) | catalogued as rs1484778754, COSV56541352, COSV56553007; called by muse, mutect2, varscan2
- PGM2 | c.999G>A p.K333= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV101126611; called by muse, mutect2, varscan2
- PLA2G4A | c.639C>T p.Y213= | Silent (SNP) | VAF 45/172 reads (26%) | catalogued as rs750211032, COSV66552643, COSV66556602; called by muse, mutect2, varscan2
- PRMT6 | c.198C>T p.R66= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV63656387; called by muse, mutect2, varscan2
- RBM12B | c.1809C>T p.F603= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs760540718, COSV67898819; called by muse, mutect2, varscan2
- RNF214 | c.84C>T p.D28= | Silent (SNP) | VAF 35/134 reads (26%) | catalogued as COSV56120888; called by muse, mutect2, varscan2
- SHANK3 | c.3921C>T p.A1307= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1418837416, COSV53190703; called by muse, mutect2
- TAF4 | c.1317G>T p.P439= | Silent (SNP) | VAF 32/74 reads (43%) | catalogued as COSV53342382; called by muse, mutect2, varscan2
- TTN | c.17655C>A p.I5885= (on ENST00000591111; = p.I4958= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV60309818; called by muse, mutect2, varscan2
- TWIST1 | c.387C>T p.A129= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV54251487; called by muse, mutect2, varscan2
- VWCE | c.1713C>T p.D571= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs778067290, COSV57114922; called by muse, mutect2, varscan2
- ZIC4 | c.735C>T p.F245= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1325919999, COSV67172232, COSV67173973; called by muse, mutect2, varscan2
- PREX2 | c.2716-2964C>T | Intron (SNP) | VAF 28/78 reads (36%) | catalogued as COSV55791297; called by muse, mutect2, varscan2
- SLC6A15 | c.756+40A>G | Intron (SNP) | VAF 32/111 reads (29%) | catalogued as COSV57029062; called by muse, mutect2, varscan2
